Somatic mutation profile of tumor specimen TCGA-QT-A7U0-01A (aliquot TCGA-QT-A7U0-01A-11D-A35D-08) from TCGA case TCGA-QT-A7U0, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 56.2 years (20,538 days).
Specimen TCGA-QT-A7U0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f77b9b0a-27f2-486c-a5df-de84ac8d3994.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QT-A7U0-10A (Blood Derived Normal), aliquot TCGA-QT-A7U0-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12856928-8a21-4db6-9654-db7a2f4af13d

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Splice Region 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPAS1 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 45/123 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55385154, COSV55385617; called by muse, mutect2, varscan2
- AGXT2 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MTMR10 | c.849C>G p.L283= | Splice Region (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- WDR11 | c.2864C>G p.P955R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP8 | c.699C>T p.Y233= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs377108884; called by muse, mutect2
